CCDI case PBCWPX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/8132361a-1e4f-47cf-8369-314b2e8ae403

Demographics
Sex at birth: female.

Biospecimens (4 samples)
- Sample 0E1NYT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0E1O0H, 0E1O0U (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E27PD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
